Somatic mutation profile of tumor specimen TARGET-20-PASBBE-09A (aliquot TARGET-20-PASBBE-09A-02D) from TARGET case TARGET-20-PASBBE, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.6 years (3,889 days).
Specimen TARGET-20-PASBBE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6efa6fc1-59ea-4107-a4bd-f1b54fb386d8.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASBBE-14A (Bone Marrow Normal), aliquot TARGET-20-PASBBE-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45b2bed7-8d15-47c7-af6d-adfd1cf523a7

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSF3R | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs796065343, COSV58963463; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYH2 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 112/238 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs144860788, COSV55439061; called by muse, mutect2, varscan2
- TRIM24 | c.2729G>T p.R910L (on ENST00000343526 / NM_015905.3; = p.R876L on NM_003852.4) | Missense Mutation (SNP) | VAF 128/296 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58970401; called by muse, mutect2, varscan2
- CEBPA | c.940_942dup p.V314dup | In Frame Ins (INS) | VAF 84/225 reads (37%) | called by mutect2, pindel, varscan2
- FES | c.807-24C>G | Intron (SNP) | VAF 92/196 reads (47%) | called by muse, mutect2, varscan2
